Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A19B, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A19B-06A (Metastatic).

10D-0-3

Melanoma; NOS

8720/3 12/14/10 lw

PATIENT HISTORY:

No clinical history given.

PRE-OP DIAGNOSIS: Melanoma.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Wide excision melanoma, back.

Site code: back, subcutaneous tissue C49.1

FINAL DIAGNOSIS:

SKIN AND SUBCUTANEOUS TISSUE, RIGHT BACK, WIDE EXCISION -
METASTATIC MELANOMA IN SKIN AND SUBCUTANEOUS TISSUE.

Source: NCI Genomic Data Commons file 38289457-cd1f-4f2d-bea8-e60c8590deaa (TCGA-ER-A19B.E9F013EB-73E0-4674-8F3A-C6BB07CCA742.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).